Somatic mutation profile of tumor specimen TCGA-49-AARE-01A (aliquot TCGA-49-AARE-01A-11D-A410-08) from TCGA case TCGA-49-AARE, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 51.7 years (18,893 days).
Specimen TCGA-49-AARE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 090b9ba2-7d58-4be9-afb3-f29b8a7e0337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AARE-11A (Solid Tissue Normal), aliquot TCGA-49-AARE-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c7b3b93-be85-483e-b423-c8ca6372c2b0

The open-access MAF lists 1,329 somatic variants for this specimen: 1,016 protein-altering or splice-affecting, 287 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 862, Silent 287, Nonsense Mutation 71, Frame Shift Del 28, Splice Site 27, Frame Shift Ins 15, Intron 12, RNA 10, Splice Region 10, 5'UTR 3, In Frame Del 2, Translation Start Site 1.

Variants (750 of 1,329; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50296596, COSV99408076; called by muse, mutect2, varscan2
- RYR1 | c.6599C>T p.A2200V | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.12); catalogued as rs193922791, CM055512, COSV62114968; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- UQCRB | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs863224258, COSV99749157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1361C>A p.P454Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs1330923268, COSV100588529; called by muse, mutect2, varscan2
- ABCA2 | c.2758G>A p.D920N (on ENST00000614293; = p.D890N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs757517721, COSV99687615; called by muse, mutect2, varscan2
- ABCA6 | c.3992G>T p.R1331I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV52644527, COSV99446466; called by muse, mutect2, varscan2
- ABCA9 | c.4110G>C p.E1370D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV100383108, COSV100383407; called by muse, mutect2, varscan2
- ABCB1 | c.2828C>A p.S943Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55959245, COSV99713048; called by muse, mutect2, varscan2
- ABCB5 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101295931; called by muse, mutect2, varscan2
- ABCB5 | c.1663C>A p.L555M (on ENST00000404938 / NM_001163941.2; = p.L110M on NM_178559.6) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328374; called by muse, mutect2, varscan2
- ABCC2 | c.3947T>G p.V1316G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100966518; called by muse, mutect2, varscan2
- ABLIM3 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100448404; called by muse, mutect2, varscan2
- AC092718.8 | c.217A>T p.N73Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100202837; called by muse, mutect2, varscan2
- AC097636.1 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV101469663, COSV101469670, COSV71309616; called by muse, mutect2, varscan2
- ACAD10 | c.2832G>T p.L944F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100564162; called by muse, mutect2, varscan2
- ACAD10 | c.2833G>C p.A945P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100564164; called by muse, mutect2, varscan2
- ACADSB | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777545593, COSV100715188; called by muse, mutect2, varscan2
- ACKR1 | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as COSV100929560; called by muse, mutect2, varscan2
- ACSF3 | c.1708A>C p.I570L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100441324; called by muse, mutect2, varscan2
- ACSM2B | c.1304C>A p.A435D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100312663; called by muse, mutect2, varscan2
- ACSM2B | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.224); catalogued as COSV100312664; called by muse, mutect2, varscan2
- ACTN2 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as COSV100856802; called by muse, mutect2, varscan2
- ADAM18 | c.1931G>T p.C644F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99695539; called by muse, mutect2
- ADAMTS13 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV100747080; called by muse, mutect2, varscan2
- ADAMTS15 | c.2318G>T p.R773L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV100143190; called by muse, mutect2, varscan2
- ADAMTS16 | c.1848C>A p.P616= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as rs376099522, COSV99941147; called by muse, mutect2, varscan2
- ADAMTS18 | c.3284G>A p.R1095K | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.139); catalogued as rs746051519, COSV51412278, COSV51422246; called by muse, mutect2, varscan2
- ADAMTS20 | c.4634C>T p.T1545I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV101239302; called by muse, mutect2, varscan2
- ADAMTS20 | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV67133682; called by muse, mutect2, varscan2
- ADAMTS7 | c.2348del p.G783Vfs*174 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs1215045224, COSV66305661; called by mutect2, varscan2
- ADARB1 | c.2096A>T p.H699L (on ENST00000360697 / NM_001346687.2; = p.H659L on NM_001112.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.036); catalogued as COSV100653828; called by mutect2, varscan2
- ADGRE3 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV99506207; called by muse, mutect2
- ADGRG7 | c.1451T>A p.L484H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99841029; called by muse, mutect2, varscan2
- ADK | c.323G>T p.G108V (on ENST00000286621; = p.G91V on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757363781, COSV54221622; called by muse, mutect2, varscan2
- AFF2 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60659976; called by muse, mutect2, varscan2
- AFF2 | c.2459A>T p.H820L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53995758, COSV99663940; called by muse, mutect2, varscan2
- AFF2 | c.3623A>T p.K1208M | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99663944; called by muse, mutect2, varscan2
- AGK | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1423127686, COSV100814625; called by muse, mutect2, varscan2
- AGXT2 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV99183753; called by muse, mutect2, varscan2
- AHRR | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1481893318, COSV100327275; called by muse, mutect2, varscan2
- AKAP17A | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs757646683, COSV100002240; called by muse, mutect2, varscan2
- AKAP3 | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57422257; called by mutect2, varscan2
- AKAP4 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1557204156, COSV100654264; called by muse, mutect2
- AKAP6 | c.2929G>T p.D977Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99800788; called by muse, mutect2, varscan2
- ALMS1 | c.7409A>G p.D2470G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100042465; called by muse, mutect2, varscan2
- ALPK1 | c.155A>C p.Q52P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51592012, COSV99454097; called by muse, mutect2, varscan2
- ALPK1 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99454100; called by muse, mutect2, varscan2
- ALS2 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99969285; called by muse, mutect2, varscan2
- ALS2 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs202084736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER1 | c.2734G>T p.V912F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100366101, COSV100366167; called by muse, mutect2, varscan2
- AMER3 | c.1160A>C p.Y387S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100366536; called by muse, mutect2, varscan2
- AMOT | c.1351G>A p.E451K (on ENST00000371959 / NM_001113490.1; = p.E42K on NM_133265.3) | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV100495056; called by muse, mutect2, varscan2
- ANAPC16 | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100191905; called by muse, mutect2, varscan2
- ANKAR | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.416); catalogued as COSV99854238; called by muse, mutect2, varscan2
- ANKRD26 | c.437del p.G146Afs*16 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as COSV65793783; called by mutect2, pindel, varscan2
- ANKRD30A | c.3598C>A p.P1200T (on ENST00000611781; = p.P1144T on NM_052997.2) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100653526; called by muse, mutect2, varscan2
- ANKRD33 | c.511G>T p.A171S (on ENST00000340970 / NM_001304459.2; = p.A296S on NM_182608.4) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1434122956, COSV100001299; called by muse, mutect2, varscan2
- ANKRD50 | c.3530C>T p.S1177L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV101538959; called by muse, mutect2, varscan2
- ANKRD7 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750600175, COSV99501130; called by muse, mutect2, varscan2
- AOC1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV100710780; called by muse, mutect2
- AOPEP | c.2296G>T p.E766* (on ENST00000375315 / NM_001193329.1; = p.E667* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99949706, COSV99949978; called by muse, mutect2, varscan2
- AP002512.3 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.05); catalogued as COSV100392511; called by muse, varscan2
- AP2M1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV99490590; called by muse, mutect2, varscan2
- APOBEC3G | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101349078; called by muse, mutect2, varscan2
- AR | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV101018258; called by muse, mutect2, varscan2
- ARF1 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99683189; called by muse, mutect2, varscan2
- ARFIP2 | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as rs1278283119, COSV99601530; called by muse, mutect2, varscan2
- ARHGAP26 | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99190937; called by muse, mutect2, varscan2
- ARHGEF17 | c.4088G>T p.G1363V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV99735622; called by muse, mutect2, varscan2
- ARHGEF6 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99166465; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100771914; called by muse, mutect2, varscan2
- ARNTL2 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV99667768; called by muse, mutect2, varscan2
- ASTN1 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV56061242, COSV56065424, COSV56078519; called by muse, mutect2, varscan2
- ATG7 | c.1429A>T p.T477S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.9); catalogued as COSV100607288; called by muse, mutect2, varscan2
- ATIC | c.1228-1G>C p.X410_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as rs1233392915, COSV99377784; called by muse, mutect2, varscan2
- ATP1A2 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100767837; called by muse, varscan2
- ATP1A4 | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100927550; called by muse, mutect2, varscan2
- ATP2A3 | c.1844A>T p.Y615F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV99989142; called by mutect2, varscan2
- ATP6V0A1 | c.2381A>T p.E794V (on ENST00000343619 / NM_001378531.1; = p.E788V on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178273736, COSV99230960; called by muse, mutect2, varscan2
- ATP6V1H | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99050955; called by muse, mutect2
- ATP7B | c.1016G>T p.R339M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV54436214, COSV99666538; called by muse, mutect2, varscan2
- ATP8A1 | c.1997A>T p.Q666L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100046176; called by muse, varscan2
- ATP8A1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100046179; called by muse, varscan2
- ATXN2 | c.1544G>C p.R515P (on ENST00000550104; = p.R355P on NM_002973.4) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376446808, COSV101112752; called by muse, mutect2, varscan2
- AUTS2 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100716898; called by muse, mutect2, varscan2
- AWAT1 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100997202; called by muse, mutect2, varscan2
- B3GAT3 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99605915; called by muse, mutect2, varscan2
- B3GNT3 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100592737; called by muse, mutect2
- B4GALNT4 | c.444T>A p.H148Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100327541; called by muse, mutect2, varscan2
- BACH2 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV57611600; called by muse, mutect2, varscan2
- BAZ1B | c.2329T>A p.W777R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100289777; called by muse, mutect2, varscan2
- BCAN | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV100228091; called by muse, mutect2, varscan2
- BCL11B | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100595524; called by muse, mutect2, varscan2
- BCL2L13 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV100456267, COSV100456268; called by muse, mutect2, varscan2
- BCOR | c.2547C>A p.H849Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV100653313; called by muse, mutect2, varscan2
- BCORL1 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753285214, COSV99499432; called by muse, mutect2, varscan2
- BCORL1 | c.2432C>A p.A811E | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99499438; called by muse, varscan2
- BIRC6 | c.13408G>T p.E4470* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV101428288; called by muse, mutect2, varscan2
- BPGM | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.385); catalogued as rs1239298017, COSV100790204; called by muse, mutect2, varscan2
- BRD2 | c.831dup p.G278Rfs*24 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | catalogued as rs1474133237; called by mutect2, varscan2
- BRF2 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as COSV99604923; called by muse, mutect2, varscan2
- BRINP2 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100838083; called by muse, mutect2, varscan2
- BRWD3 | c.463T>G p.C155G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100956052; called by muse, mutect2, varscan2
- BTBD3 | c.226A>C p.S76R | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99655875; called by muse, mutect2, varscan2
- BUB1B | c.2129C>G p.T710S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.519); catalogued as COSV99806895; called by muse, mutect2, varscan2
- C10orf120 | c.399T>A p.C133* | Nonsense Mutation (SNP) | VAF 23/171 reads (13%) | catalogued as COSV100271622; called by muse, mutect2, varscan2
- C10orf82 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV65024529; called by muse, mutect2, varscan2
- C3orf20 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as rs776476919, COSV99513941; called by muse, mutect2, varscan2
- C5orf34 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100175454; called by muse, mutect2, varscan2
- C5orf34 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100175455; called by muse, varscan2
- CA12 | c.748-1G>T p.X250_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99458267; called by muse, mutect2
- CACNA1E | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV100702616; called by muse, mutect2, varscan2
- CACNA1F | c.4183G>T p.G1395* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100544816, COSV59905779; called by muse, mutect2, varscan2
- CACNA1I | c.2771T>A p.L924Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100360270; called by muse, mutect2, varscan2
- CACNA1I | c.5749G>C p.D1917H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100360274; called by muse, mutect2, varscan2
- CACNB2 | c.910C>A p.L304M (on ENST00000324631 / NM_201596.3; = p.L249M on NM_000724.4) | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56647339, COSV99994555; called by muse, mutect2, varscan2
- CACTIN | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99698279; called by muse, mutect2, varscan2
- CADPS2 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV100462741, COSV57364316; called by muse, mutect2, varscan2
- CAMP | c.391-2A>T p.X131_splice (on ENST00000296435; = p.X128_splice on NM_004345.5) | Splice Site (SNP) | VAF 26/132 reads (20%) | catalogued as COSV99601231; called by muse, mutect2, varscan2
- CASP3 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV100394980; called by muse, mutect2, varscan2
- CASQ1 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100927294, COSV63624121; called by muse, mutect2, varscan2
- CAV3 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100373170; called by muse, mutect2, varscan2
- CC2D2A | c.876G>C p.Q292H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101052777; called by muse, mutect2, varscan2
- CCDC114 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100196758; called by muse, mutect2, varscan2
- CCDC116 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 34/84 reads (40%) | catalogued as COSV53039162, COSV99489334; called by muse, mutect2, varscan2
- CCDC171 | c.2831C>A p.A944D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs771505107, COSV99900661; called by muse, mutect2, varscan2
- CCDC33 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51435115, COSV99166010; called by muse, mutect2, varscan2
- CCDC40 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV99481433; called by muse, mutect2, varscan2
- CCDC6 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs755840504, COSV99569472; called by muse, mutect2, varscan2
- CCDC73 | c.1050T>C p.H350= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100067427; called by muse, mutect2, varscan2
- CCIN | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100631826; called by muse, mutect2, varscan2
- CCNB3 | c.4102G>T p.E1368* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99329046; called by muse, mutect2, varscan2
- CCT6B | c.845G>T p.C282F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV100030665; called by muse, varscan2
- CD14 | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100117548; called by muse, mutect2, varscan2
- CD44 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53530339; called by muse, mutect2, varscan2
- CD5 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100759817; called by muse, mutect2, varscan2
- CD8B | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100514511; called by mutect2, varscan2
- CDC73 | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV100813866; called by muse, mutect2, varscan2
- CDCP2 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100313477; called by muse, mutect2, varscan2
- CDH10 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.817); catalogued as COSV100051420, COSV52594100; called by muse, mutect2, varscan2
- CDH10 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.05); catalogued as rs1425828005, COSV100051422, COSV52574911; called by muse, mutect2, varscan2
- CDH7 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.277); catalogued as COSV100542365, COSV59884609; called by muse, mutect2, varscan2
- CDH8 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV54863176; called by muse, mutect2, varscan2
- CDH9 | c.812-1G>T p.X271_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as rs1258479228, COSV99144669; called by muse, mutect2, varscan2
- CEACAM5 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.794); catalogued as COSV99703919; called by muse, mutect2
- CELF4 | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as rs1331125816, COSV100611659; called by muse, mutect2, varscan2
- CENPE | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99477911; called by muse, mutect2, varscan2
- CEP112 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101210752; called by muse, mutect2, varscan2
- CEP120 | c.2061G>T p.W687C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753729269, COSV100071097; called by muse, mutect2, varscan2
- CEP170 | c.2791C>G p.P931A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100317071, COSV100317249; called by mutect2, varscan2
- CEP170 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1250022236, COSV100317074; called by muse, mutect2, varscan2
- CEP78 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99450452; called by muse, mutect2, varscan2
- CFAP44 | c.1159G>T p.G387* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs1432533328, COSV99869529; called by muse, varscan2
- CFAP47 | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV99935022; called by mutect2, varscan2
- CFAP47 | c.2677G>T p.G893* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | catalogued as rs1376066532, COSV99935026, COSV99935879; called by muse, mutect2, varscan2
- CFAP65 | c.2109C>A p.C703* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100445135, COSV58563047; called by muse, mutect2
- CFAP91 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1272060443, COSV56343909, COSV99847112; called by muse, mutect2, varscan2
- CFAP97 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as rs1289951392, COSV99703437; called by muse, mutect2, varscan2
- CFTR | c.580-1G>C p.X194_splice | Splice Site (SNP) | VAF 39/143 reads (27%) | catalogued as CS971649, COSV99136146; called by muse, mutect2, varscan2
- CHD6 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1274369410, COSV100498257; called by muse, mutect2, varscan2
- CHD8 | c.5731G>T p.A1911S (on ENST00000646647 / NM_001170629.2; = p.A1632S on NM_020920.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100765308; called by muse, mutect2, varscan2
- CHFR | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57177121, COSV99905302; called by muse, mutect2, varscan2
- CHM | c.941-1G>C p.X314_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as CS137305, COSV100753273; called by mutect2, varscan2
- CHMP2B | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99773408; called by muse, mutect2, varscan2
- CHP2 | c.133T>A p.Y45N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as COSV100270159; called by muse, mutect2, varscan2
- CHRM2 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV100281268, COSV104413279; called by muse, mutect2, varscan2
- CHRM3 | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99698381; called by mutect2, varscan2
- CHRNA3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.788); catalogued as rs751388943, COSV100468268; called by muse, mutect2
- CHSY3 | c.1398G>T p.W466C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519082, COSV100519240; called by muse, mutect2
- CIAO3 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52403534, COSV99284845; called by muse, mutect2, varscan2
- CILP | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs765770685, COSV99973380; called by muse, mutect2, varscan2
- CIPC | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100694463; called by mutect2, varscan2
- CLCN4 | c.1418T>C p.M473T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101073811; called by muse, mutect2, varscan2
- CLCN4 | c.1527C>A p.D509E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as rs918406808, COSV101073813; called by muse, mutect2, varscan2
- CLEC14A | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100643571; called by muse, mutect2
- CLEC1A | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as rs1462554781, COSV100191447; called by muse, mutect2, varscan2
- CLINT1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99754062; called by muse, mutect2, varscan2
- CLK1 | c.1104T>G p.I368M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100362278; called by muse, mutect2, varscan2
- CLTC | c.1369-1G>T p.X457_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99292272; called by muse, mutect2, varscan2
- CLVS2 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51568074; called by muse, mutect2, varscan2
- CMYA5 | c.11819C>T p.P3940L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1420207821, COSV101405663; called by muse, mutect2
- CNKSR1 | c.708G>C p.Q236H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100836736, COSV64163226; called by muse, mutect2, varscan2
- CNKSR2 | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99668500; called by muse, mutect2, varscan2
- CNOT2 | c.1133T>C p.L378S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99972627; called by muse, mutect2, varscan2
- CNTN1 | c.3032G>C p.G1011A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.067); catalogued as COSV100751385; called by mutect2, varscan2
- CNTN4 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV101281165, COSV101281354; called by muse, mutect2, varscan2
- CNTNAP5 | c.1329C>A p.S443R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV101443545; called by muse, mutect2, varscan2
- COG3 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100596513, COSV63073513; called by muse, mutect2, varscan2
- COL11A1 | c.2180G>C p.G727A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62198879; called by muse, mutect2, varscan2
- COL19A1 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100506281; called by muse, mutect2, varscan2
- COL3A1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs1422693997, COSV100483017; called by muse, mutect2, varscan2
- COL4A1 | c.4852G>T p.G1618C | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011173; called by muse, mutect2, varscan2
- COL4A4 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV100306828; called by muse, varscan2
- COL4A6 | c.2399G>T p.R800L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as COSV100564090; called by muse, mutect2, varscan2
- COL4A6 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564092; called by muse, mutect2, varscan2
- COPB2 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292442429, COSV100300646; called by muse, mutect2, varscan2
- COQ8A | c.812G>C p.R271P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100825669, COSV64656938; called by muse, mutect2, varscan2
- COX7B2 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100259744, COSV57218524; called by muse, mutect2, varscan2
- CPNE6 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as COSV53745631, COSV99393430; called by muse, varscan2
- CPXM2 | c.2111T>C p.M704T | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV99582201; called by muse, mutect2, varscan2
- CR1 | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs191714506, COSV100887604; called by muse, mutect2, varscan2
- CRB1 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100958856; called by muse, mutect2, varscan2
- CRB2 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as rs755149340, COSV100749638; called by muse, mutect2
- CRTAC1 | c.1671C>A p.C557* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100085527; called by muse, mutect2, varscan2
- CSMD1 | c.8382G>T p.V2794= (on ENST00000520002; = p.V2793= on NM_033225.6) | Splice Region (SNP) | VAF 9/16 reads (56%) | catalogued as rs1228949792, COSV59289042; called by muse, mutect2, varscan2
- CSMD3 | c.9193G>T p.G3065C (on ENST00000297405 / NM_001363185.1; = p.G2896C on NM_052900.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99834152; called by muse, mutect2, varscan2
- CSMD3 | c.8087G>T p.S2696I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99834154; called by muse, mutect2, varscan2
- CSMD3 | c.7185C>A p.C2395* (on ENST00000297405 / NM_001363185.1; = p.C2291* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs79806499, COSV99834158; called by mutect2, varscan2
- CTSG | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1330240537, COSV99361518; called by mutect2, varscan2
- CTTNBP2 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99353944; called by muse, mutect2, varscan2
- CUBN | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as COSV100910588; called by muse, mutect2
- CUEDC1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1286968819, COSV100804733; called by muse, mutect2, varscan2
- CUX2 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99919644; called by muse, mutect2, varscan2
- CXCR2 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100578944; called by mutect2, varscan2
- CXXC1 | c.1241A>T p.Q414L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1392763448, COSV99496352; called by muse, mutect2, varscan2
- CXorf56 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100233381, COSV57438239; called by mutect2, varscan2
- CYP11B1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1293621967, COSV99455108; called by muse, mutect2, varscan2
- CYP1A2 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1263283830, COSV100673896; called by muse, mutect2, varscan2
- CYP4F2 | c.1314+1G>T p.X438_splice | Splice Site (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99686000; called by muse, mutect2, varscan2
- DAND5 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100397252; called by muse, varscan2
- DAO | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99948601; called by muse, mutect2
- DBN1 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99445978; called by muse, mutect2
- DCAF12L1 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV64421211, COSV64422121; called by muse, mutect2, varscan2
- DCAF12L1 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100948289; called by muse, mutect2, varscan2
- DCAF12L2 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758602, COSV100758766; called by muse, mutect2, varscan2
- DCAF12L2 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV100758603; called by muse, mutect2, varscan2
- DCAF4L1 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100295730; called by muse, mutect2, varscan2
- DCDC1 | c.5122G>C p.A1708P (on ENST00000597505 / NM_001367979.1; = p.A815P on NM_020869.3) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); catalogued as COSV100360519; called by muse, mutect2
- DCDC2 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV101015390; called by muse, mutect2, varscan2
- DCDC2B | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1376293322, COSV99356580; called by muse, mutect2, varscan2
- DCHS1 | c.2983G>T p.G995W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100202040; called by muse, mutect2
- DDX1 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774565569, COSV99246288; called by muse, mutect2, varscan2
- DDX42 | c.472-1G>T p.X158_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100834927; called by muse, mutect2, varscan2
- DDX59 | c.1318A>G p.K440E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1417064442, COSV100494538; called by muse, mutect2
- DDX60 | c.3718G>A p.V1240I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.063); catalogued as COSV101190465; called by muse, mutect2, varscan2
- DEFB135 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs778893958, COSV101198549; called by mutect2, varscan2
- DELE1 | c.1084A>C p.T362P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99519799; called by muse, mutect2, varscan2
- DENND1C | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101200202; called by muse, mutect2, varscan2
- DENND4C | c.4709C>A p.A1570D (on ENST00000434457 / NM_001330640.2; = p.A1521D on NM_017925.7) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV63008458; called by muse, mutect2, varscan2
- DEPDC4 | c.4G>C p.V2L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100147349, COSV54553188, COSV54553229; called by muse, mutect2, varscan2
- DGKA | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100093068; called by muse, mutect2, varscan2
- DGKG | c.2277G>T p.T759= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs149298788; called by mutect2, varscan2
- DGKI | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99934458; called by muse, mutect2
- DHRSX | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100585557; called by muse, mutect2, varscan2
- DHX29 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99287289; called by muse, mutect2, varscan2
- DHX9 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100841405; called by muse, mutect2, varscan2
- DHX9 | c.2863del p.E955Kfs*10 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | catalogued as rs1350324393; called by pindel, varscan2
- DIAPH3 | c.630G>T p.W210C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933521; called by muse, varscan2
- DLC1 | c.827G>C p.S276T | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99363119; called by muse, mutect2, varscan2
- DLEC1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100342336; called by muse, mutect2, varscan2
- DLG3 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1299586193, COSV99529529; called by muse, mutect2, varscan2
- DLG4 | c.881A>T p.Y294F (on ENST00000399506 / NM_001321075.3; = p.Y337F on NM_001365.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100263700; called by muse, mutect2, varscan2
- DMD | c.10595A>G p.E3532G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1023553628, COSV100627215; called by muse, mutect2, varscan2
- DMD | c.3532G>C p.E1178Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100819650, COSV104419538, COSV63784660; called by muse, varscan2
- DMD | c.717G>T p.L239F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1222379202, COSV99922373; called by muse, mutect2, varscan2
- DMD | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as CM051908, COSV55886844, COSV99922377; called by muse, mutect2, varscan2
- DMRT3 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99505858; called by muse, mutect2, varscan2
- DNAH1 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV101325770; called by muse, mutect2, varscan2
- DNAH11 | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as COSV100179236; called by muse, mutect2, varscan2
- DNAH11 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1393527464, COSV100179238; called by muse, mutect2, varscan2
- DNAH8 | c.4969G>T p.D1657Y | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs1352768772, COSV59426660, COSV59468553; called by muse, mutect2, varscan2
- DNAI2 | c.1397T>A p.L466H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100209776; called by muse, varscan2
- DNAJC10 | c.1383A>T p.Q461H | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV99899236; called by muse, mutect2, varscan2
- DNAJC15 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs971003848, COSV101004951; called by muse, mutect2, varscan2
- DOCK11 | c.558+2T>A p.X186_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99353778; called by muse, mutect2, varscan2
- DOCK3 | c.3560T>A p.I1187N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV99811947; called by muse, mutect2, varscan2
- DPH6 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV99853578; called by mutect2, varscan2
- DPYSL2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.891); catalogued as COSV100233579, COSV60784864; called by muse, mutect2, varscan2
- DPYSL3 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV100575107; called by muse, varscan2
- DRP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100871910; called by muse, mutect2, varscan2
- DSG2 | c.379-1G>T p.X127_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99853158; called by mutect2, varscan2
- DSG3 | c.372G>T p.L124= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99934154; called by muse, mutect2, varscan2
- DUSP6 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99684052; called by muse, mutect2, varscan2
- DYNC1H1 | c.4762G>T p.V1588F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100794883; called by muse, mutect2, varscan2
- DYSF | c.3173G>C p.R1058T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1387342780, COSV99247026; called by muse, mutect2, varscan2
- EBF3 | c.782-1G>A p.X261_splice (on ENST00000355311 / NM_001375392.1; = p.X252_splice on NM_001005463.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100799201; called by muse, mutect2, varscan2
- EFHB | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV55548426, COSV99859559; called by muse, mutect2, varscan2
- EFL1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99186938; called by muse, mutect2, varscan2
- EGLN3 | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.18); catalogued as COSV51654129, COSV99164342; called by muse, mutect2, varscan2
- EID3 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723454; called by muse, mutect2, varscan2
- ELF4 | c.1672G>T p.G558W | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100257360; called by muse, mutect2, varscan2
- ELF4 | c.1336A>G p.S446G | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100257361; called by muse, mutect2
- ELN | c.2261G>C p.R754P (on ENST00000320399 / NM_001278939.1; = p.R721P on NM_000501.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782197482, COSV52706718, COSV99332647; called by muse, mutect2, varscan2
- ELSPBP1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100353621; called by muse, mutect2
- EMC7 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99854866; called by mutect2, varscan2
- ENOSF1 | c.440G>C p.G147A (on ENST00000340116 / NM_001354066.2; = p.G99A on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV99201070; called by muse, mutect2, varscan2
- ENTHD1 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as rs199789187, COSV100288747; called by muse, mutect2
- EPB41L3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549143, COSV59460312; called by muse, mutect2, varscan2
- EPG5 | c.76T>A p.Y26N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99957246; called by muse, mutect2, varscan2
- EPG5 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99957248; called by muse, mutect2, varscan2
- EPHB3 | c.2389G>T p.G797C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383066; called by muse, mutect2, varscan2
- EPN1 | c.1541C>T p.P514L (on ENST00000270460 / NM_001321263.1; = p.P488L on NM_013333.3) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1420124375, COSV99321884; called by muse, mutect2, varscan2
- ERBB4 | c.2161G>T p.V721L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53608071, COSV99623481; called by muse, mutect2, varscan2
- ERCC6L | c.3500C>A p.A1167D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100559110; called by muse, mutect2, varscan2
- ERCC6L | c.1937A>C p.H646P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100559112; called by muse, mutect2, varscan2
- ESF1 | c.2281C>G p.R761G | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52523639, COSV99176362; called by muse, mutect2, varscan2
- ESRRG | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100752897; called by muse, mutect2, varscan2
- EVX1 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763941; called by muse, mutect2, varscan2
- EVX2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100420669; called by mutect2, varscan2
- EXOC1 | c.2225G>T p.R742L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100637863; called by muse, mutect2, varscan2
- EZHIP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV100539681; called by muse, mutect2, varscan2
- EZHIP | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs1557318866, COSV57955490, COSV57955722; called by muse, mutect2, varscan2
- FAAH2 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100887293; called by muse, mutect2, varscan2
- FAM110B | c.1084A>G p.R362G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1290068816, COSV100826133; called by muse, mutect2, varscan2
- FAM153B | c.736-1G>C p.X246_splice (on ENST00000253490; = p.X169_splice on NM_001265615.1) | Splice Site (SNP) | VAF 14/142 reads (10%) | catalogued as COSV99498910; called by muse, mutect2
- FAM167A | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99453260; called by mutect2, varscan2
- FAM199X | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100245545, COSV55433472; called by muse, mutect2, varscan2
- FAM3D | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV100716809; called by muse, mutect2, varscan2
- FAM3D | c.475A>T p.R159W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100716813; called by muse, mutect2, varscan2
- FAM47A | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV100649891; called by muse, varscan2
- FAM47A | c.1409C>A p.P470H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100649893; called by muse, varscan2
- FAM47A | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.546); catalogued as COSV60497114; called by muse, mutect2, varscan2
- FAM71B | c.1586A>T p.K529M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437584574, COSV100262099; called by muse, mutect2, varscan2
- FAM83C | c.1406G>C p.G469A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100981567; called by muse, mutect2, varscan2
- FANCM | c.956A>T p.N319I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99951048; called by muse, mutect2, varscan2
- FAT4 | c.6766G>T p.V2256F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as COSV100628603; called by muse, mutect2, varscan2
- FBN2 | c.8200G>T p.V2734F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99327431; called by muse, mutect2, varscan2
- FBN2 | c.6886G>T p.D2296Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99327435; called by muse, mutect2, varscan2
- FBXL18 | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1277287115, COSV101212066; called by muse, mutect2, varscan2
- FBXO10 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99446300; called by muse, mutect2, varscan2
- FBXO24 | c.1695G>T p.R565S (on ENST00000241071 / NM_033506.3; = p.R603S on NM_012172.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99575346; called by muse, mutect2, varscan2
- FBXO40 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as rs1364777817, COSV100573159; called by muse, mutect2, varscan2
- FCGR3B | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99670534, COSV99670797; called by mutect2, varscan2
- FER1L6 | c.3095A>T p.Q1032L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV101205845; called by muse, mutect2, varscan2
- FETUB | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs370905116, COSV99408997; called by muse, mutect2, varscan2
- FGF23 | c.733C>A p.R245S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99426404; called by muse, mutect2, varscan2
- FGFR4 | c.332A>C p.Q111P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99449816; called by muse, mutect2, varscan2
- FKBP6 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.023); catalogued as COSV99333706, COSV99333956; called by muse, mutect2, varscan2
- FLG2 | c.5549A>T p.Q1850L | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101165865; called by muse, mutect2, varscan2
- FLG2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | catalogued as COSV101165866, COSV66169403; called by muse, mutect2, varscan2
- FLI1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1018854833, COSV99857720; called by muse, mutect2
- FLNA | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61043651; called by muse, mutect2, varscan2
- FLNC | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.774); catalogued as COSV100368098; called by muse, mutect2, varscan2
- FLNC | c.7634C>A p.P2545H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368100; called by muse, mutect2, varscan2
- FLNC | c.7927C>A p.P2643T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99972493; called by mutect2, varscan2
- FLT1 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56734695, COSV99156721; called by muse, mutect2, varscan2
- FMNL3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs747296458, COSV99526266; called by muse, mutect2, varscan2
- FMO1 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100707770; called by muse, mutect2, varscan2
- FMO2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.073); catalogued as COSV52946876; called by muse, mutect2, varscan2
- FOXB1 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV101249817; called by muse, mutect2, varscan2
- FOXC2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1026183412, COSV100234254; called by muse, mutect2, varscan2
- FOXG1 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284868040, COSV57397070; called by mutect2, varscan2
- FOXR1 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV100392914; called by muse, mutect2, varscan2
- FREM2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs868059163, COSV99748744; called by muse, mutect2
- FRMD7 | c.961T>G p.L321V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as COSV100049014; called by muse, mutect2, varscan2
- FRMPD4 | c.3094G>T p.A1032S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as COSV101042862; called by muse, mutect2, varscan2
- FSTL4 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV99532577; called by muse, mutect2, varscan2
- FTCD | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99385052; called by muse, mutect2, varscan2
- FTHL17 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100784298, COSV63267954; called by muse, mutect2, varscan2
- GAB4 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV101271981; called by muse, mutect2, varscan2
- GABRA2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62916360; called by muse, mutect2, varscan2
- GABRA2 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.007); catalogued as COSV100734252; called by muse, mutect2, varscan2
- GABRA3 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100942702; called by muse, mutect2, varscan2
- GABRB1 | c.913G>C p.A305P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99781611; called by muse, mutect2, varscan2
- GABRG3 | c.1307T>G p.I436R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100407137; called by muse, mutect2, varscan2
- GALNT18 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs141880350, COSV99924595; called by muse, mutect2, varscan2
- GARNL3 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV100150252, COSV59224428; called by muse, mutect2
- GATA1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64962318; called by muse, mutect2, varscan2
- GBA3 | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101545511; called by muse, varscan2
- GCSAML | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs1373005614, COSV100825954, COSV63577633; called by muse, mutect2, varscan2
- GLIS1 | c.104C>A p.A35E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs746970092, COSV100390026, COSV56546293; called by muse, mutect2, varscan2
- GON4L | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99674268; called by muse, mutect2, varscan2
- GPR39 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100257731; called by muse, mutect2, varscan2
- GPR52 | c.1057A>T p.R353W | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99270175; called by muse, mutect2, varscan2
- GPRIN1 | c.1401A>G p.I467M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99991600; called by muse, mutect2, varscan2
- GPX2 | c.257T>A p.L86H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753435037, COSV100767446; called by muse, mutect2, varscan2
- GRAMD2B | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99587070; called by muse, mutect2, varscan2
- GRAP2 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100702985; called by muse, mutect2, varscan2
- GRIK2 | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV59742177; called by muse, varscan2
- GRIN2B | c.4014C>A p.H1338Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs758288071, COSV101663033; called by mutect2, varscan2
- GRK3 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as rs373371487, COSV100151550; called by muse, mutect2, varscan2
- GRM3 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100862537; called by muse, mutect2, varscan2
- GRM5 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100551905; called by muse, mutect2, varscan2
- GRM7 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs755371859, COSV100736531; called by muse, mutect2, varscan2
- GSE1 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99496536; called by muse, mutect2, varscan2
- GTF3C3 | c.549T>A p.Y183* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99826715; called by muse, mutect2, varscan2
- GTSF1 | c.131T>A p.V44D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100007484; called by muse, mutect2, varscan2
- GUCY2F | c.2514G>C p.L838F | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99484982; called by muse, mutect2, varscan2
- GUCY2F | c.2038G>T p.G680W | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54309399, COSV99484984; called by muse, varscan2
- GUCY2F | c.2037T>A p.D679E | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99484986; called by muse, varscan2
- GUCY2F | c.1555C>A p.H519N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as COSV99484988; called by muse, mutect2, varscan2
- H4-16 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100797598, COSV100797641; called by muse, mutect2, varscan2
- HCN1 | c.659G>C p.S220T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.086); catalogued as COSV100300221, COSV57531920; called by muse, mutect2, varscan2
- HDAC6 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100490835; called by mutect2, varscan2
- HDLBP | c.3106G>T p.E1036* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100190613; called by mutect2, varscan2
- HDLBP | c.811A>C p.T271P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.522); catalogued as COSV100190616; called by muse, mutect2, varscan2
- HECTD1 | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs376639276; called by muse, mutect2, varscan2
- HEG1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100230498; called by mutect2, varscan2
- HEPH | c.2802G>T p.W934C (on ENST00000343002; = p.W667C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100294843, COSV57960267; called by muse, mutect2, varscan2
- HERC4 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1303336428, COSV99516981; called by muse, mutect2
- HIVEP3 | c.5092G>T p.G1698C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as COSV99912599; called by muse, mutect2, varscan2
- HMGCS2 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.193); catalogued as COSV101024791; called by muse, mutect2, varscan2
- HMX2 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.164); catalogued as rs1017991178, COSV100378762; called by muse, mutect2
- HNRNPUL2 | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100079600; called by muse, mutect2, varscan2
- HOXA1 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs901977586, COSV100547368; called by muse, mutect2, varscan2
- HOXB3 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as rs1383260397, COSV100290650; called by muse, mutect2, varscan2
- HOXC11 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.267); catalogued as COSV99678429; called by muse, mutect2, varscan2
- HR | c.2893C>A p.L965I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs751686546, COSV100455819; called by muse, mutect2, varscan2
- HS2ST1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as rs1454117965, COSV100777737; called by muse, mutect2, varscan2
- HUWE1 | c.1975C>G p.L659V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99474166; called by muse, mutect2
- IFFO1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100351109; called by muse, mutect2, varscan2
- IGF1R | c.752G>C p.C251S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99151392; called by muse, mutect2, varscan2
- IGHV4-28 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as rs371198751; called by muse, varscan2
- IGKV1-16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/139 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs766218057; called by muse, varscan2
- IGKV2D-28 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV101494560; called by mutect2, varscan2
- IGSF1 | c.2207C>A p.T736K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV100812084; called by muse, mutect2, varscan2
- IKZF2 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100563536; called by muse, mutect2, varscan2
- IL18R1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99294930, COSV99295100; called by muse, mutect2, varscan2
- IL1RAPL2 | c.815G>C p.S272T | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV100781276, COSV61157460; called by muse, mutect2, varscan2
- INO80D | c.309G>T p.R103S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.985); catalogued as rs1211905811, COSV101305840; called by muse, mutect2
- INPP5D | c.2468G>A p.R823Q (on ENST00000445964 / NM_001017915.3; = p.R822Q on NM_005541.5) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100856794; called by muse, mutect2, varscan2
- INSC | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1451768374, COSV101089174; called by mutect2, varscan2
- IPMK | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV100880320; called by muse, mutect2, varscan2
- IQCK | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); catalogued as COSV100244845; called by muse, mutect2, varscan2
- IQSEC2 | c.2188T>A p.C730S (on ENST00000642864 / NM_001111125.3; = p.C525S on NM_015075.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.365); catalogued as COSV100944906; called by muse, mutect2, varscan2
- IQSEC3 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1555083101, COSV100407169; called by muse, mutect2
- IQUB | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100227095; called by muse, mutect2, varscan2
- ISL1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs777784838, COSV100045396; called by mutect2, varscan2
- ITGA1 | c.2521G>T p.V841F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV50879811; called by mutect2, varscan2
- ITGA11 | c.2642G>A p.C881Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100241501; called by muse, mutect2, varscan2
- ITIH2 | c.596A>T p.Y199F | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100623291; called by muse, mutect2, varscan2
- ITPR3 | c.1843G>T p.V615L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100967343; called by muse, mutect2, varscan2
- JAK2 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1393954444, COSV101073273; called by muse, mutect2, varscan2
- KCNA1 | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); catalogued as COSV101230251, COSV66838239; called by muse, mutect2, varscan2
- KCNJ3 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99715793; called by muse, mutect2, varscan2
- KCNJ3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.007); catalogued as COSV54536205, COSV99715796; called by muse, mutect2
- KCNS2 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV54639393, COSV99751133; called by muse, mutect2, varscan2
- KCNT2 | c.1358C>G p.A453G | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV99653678; called by muse, mutect2, varscan2
- KDM5A | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV101238830; called by muse, mutect2, varscan2
- KDM5B | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99350598; called by muse, mutect2, varscan2
- KHDRBS1 | c.1152A>T p.E384D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV100306179; called by muse, mutect2, varscan2
- KIAA0100 | c.4935G>T p.Q1645H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101197312; called by muse, mutect2, varscan2
- KIDINS220 | c.1366A>G p.M456V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99875694; called by muse, mutect2, varscan2
- KIF14 | c.2461A>G p.K821E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100950850; called by muse, mutect2, varscan2
- KIF27 | c.1755T>G p.F585L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99926976; called by muse, mutect2, varscan2
- KIF2B | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99275350; called by muse, mutect2, varscan2
- KIF4B | c.3644C>A p.A1215D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.209); catalogued as COSV101469291; called by muse, mutect2, varscan2
- KLHL38 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384378; called by muse, mutect2, varscan2
- KLRC2 | c.287-2A>C p.X96_splice | Splice Site (SNP) | VAF 8/86 reads (9%) | catalogued as COSV101122695; called by muse, mutect2
- KLRD1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60274668; called by muse, mutect2, varscan2
- KLRD1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60275356; called by muse, mutect2, varscan2
- KNL1 | c.4622A>T p.N1541I (on ENST00000346991 / NM_170589.5; = p.N1515I on NM_144508.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100706484; called by muse, mutect2, varscan2
- KNTC1 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs556183893, COSV100063575; called by mutect2, varscan2
- KRBA1 | c.2473G>C p.A825P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1365520724, COSV99752669; called by muse, mutect2
- KRTAP22-1 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | PolyPhen benign (0.003); catalogued as COSV100588919; called by muse, mutect2
- KRTAP5-11 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100651805; called by muse, mutect2, varscan2
- KRTAP6-2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | PolyPhen possibly damaging (0.867); catalogued as rs1482909057, COSV100588928, COSV58182999; called by muse, mutect2, varscan2
- KRTAP9-3 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.931); catalogued as COSV101370156; called by muse, mutect2, varscan2
- LACTB2 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV99399452; called by muse, mutect2, varscan2
- LAMB4 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1461606687, COSV99222414, COSV99224028; called by mutect2, varscan2
- LHX8 | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV99633193, COSV99633738; called by muse, mutect2, varscan2
- LIG4 | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.177); catalogued as COSV100799901; called by mutect2, varscan2
- LIN7C | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs766145158, COSV53415422, COSV99536213; called by muse, mutect2, varscan2
- LLCFC1 | c.289G>T p.V97L (on ENST00000458732; = p.V66L on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.164); catalogued as COSV100787072; called by muse, mutect2, varscan2
- LPAR4 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV101425119, COSV70912620; called by muse, mutect2, varscan2
- LPAR4 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV101425120, COSV104437147; called by mutect2, varscan2
- LPAR4 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs772724423, COSV101425121; called by muse, mutect2, varscan2
- LPIN1 | c.1658G>A p.W553* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99877558; called by muse, mutect2, varscan2
- LRIT2 | c.1262A>C p.D421A | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100258869; called by muse, mutect2
- LRP1B | c.4018C>A p.L1340M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV67218133; called by muse, mutect2, varscan2
- LRP5 | c.2866A>T p.I956F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as COSV99591981; called by muse, mutect2, varscan2
- LRRC43 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.742); catalogued as COSV100336728; called by muse, mutect2, varscan2
- LRRC7 | c.2044C>A p.P682T (on ENST00000651989 / NM_001370785.2; = p.P649T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99226842; called by muse, mutect2, varscan2
- LRRC7 | c.2045C>A p.P682H (on ENST00000651989 / NM_001370785.2; = p.P649H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99226843; called by muse, mutect2, varscan2
- LRRC7 | c.4677G>T p.K1559N (on ENST00000651989 / NM_001370785.2; = p.K1479N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99226846; called by muse, mutect2, varscan2
- LRRK1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV99439969; called by muse, mutect2, varscan2
- LRRK2 | c.6633G>T p.K2211N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.476); catalogued as COSV100110163; called by muse, varscan2
- LRRK2 | c.6634G>T p.E2212* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100110164; called by muse, varscan2
- LRRN3 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100070471; called by muse, mutect2, varscan2
- LRTM2 | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs746248570, COSV99765671; called by muse, mutect2, varscan2
- LTN1 | c.630-1G>T p.X210_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as rs1275150804, COSV63733052, COSV63733820; called by muse, mutect2
- LYST | c.3940-1G>T p.X1314_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101089366; called by mutect2, varscan2
- MAGEA11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); catalogued as COSV100290510; called by muse, mutect2, varscan2
- MAGEB3 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV100854697, COSV64397679; called by muse, mutect2, varscan2
- MAGEB4 | c.407T>A p.L136Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100974969; called by muse, mutect2, varscan2
- MAGEC1 | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99595690; called by muse, mutect2, varscan2
- MAGEL2 | c.2513C>A p.P838Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.875); catalogued as rs1297997260, COSV100045934; called by muse, mutect2, varscan2
- MAGEL2 | c.2512C>A p.P838T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV100045935; called by muse, mutect2, varscan2
- MAGI2 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100834493; called by muse, mutect2, varscan2
- MAML3 | c.2774T>C p.I925T | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV101558413; called by muse, mutect2, varscan2
- MAP3K13 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV53986243, COSV53988542; called by muse, mutect2, varscan2
- MAPK8 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV100827415; called by muse, mutect2, varscan2
- MAPKBP1 | c.4444A>C p.S1482R (on ENST00000456763 / NM_001128608.2; = p.S1476R on NM_014994.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as COSV99529430; called by muse, mutect2, varscan2
- MAT1A | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as CM1311638, COSV100944441; called by muse, mutect2, varscan2
- MCF2L2 | c.2218C>A p.R740S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192550; called by muse, mutect2, varscan2
- MCM10 | c.1856G>T p.G619V (on ENST00000484800 / NM_182751.3; = p.G618V on NM_018518.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV101098130; called by muse, mutect2, varscan2
- MED12L | c.5015C>G p.S1672C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99853117; called by mutect2, varscan2
- MED13L | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV99928834; called by muse, mutect2, varscan2
- MED26 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659990; called by muse, mutect2, varscan2
- MEGF10 | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99174943; called by muse, mutect2, varscan2
- MEP1A | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs867782131, COSV100042706, COSV57917681; called by muse, varscan2
- METTL17 | c.248T>A p.M83K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100228214; called by muse, varscan2
- METTL17 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100228216; called by muse, varscan2
- MGAT4C | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100152944; called by muse, mutect2, varscan2
- MGAT5B | c.1619C>T p.P540L (on ENST00000569840 / NM_001199172.2; = p.P538L on NM_144677.3) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432921274, COSV100047993; called by muse, mutect2, varscan2
- MICAL2 | c.3314C>T p.T1105I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as COSV99817460; called by muse, mutect2, varscan2
- MIER2 | c.682T>G p.W228G | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53396708, COSV99316368; called by muse, mutect2, varscan2
- MINDY4 | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV99518643; called by muse, mutect2, varscan2
- MITF | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.205); catalogued as rs559222331; called by mutect2, varscan2
- MKNK2 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99170268; called by muse, mutect2, varscan2
- MMAA | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1203402362, COSV99849816; called by muse, mutect2, varscan2
- MMP16 | c.1373G>T p.R458I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1314246709, COSV99685472; called by muse, varscan2
- MNDA | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933333; called by muse, mutect2, varscan2
- MOB4 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52097159, COSV99291068; called by mutect2, varscan2
- MOCOS | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1258940139, COSV99733352; called by muse, mutect2, varscan2
- MOCS1 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99225691; called by muse, mutect2, varscan2
- MOGAT3 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99777155; called by muse, mutect2, varscan2
- MON2 | c.5146G>A p.E1716K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.325); catalogued as COSV99742535; called by muse, mutect2, varscan2
- MPPED1 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501235, COSV100501354; called by muse, mutect2, varscan2
- MPRIP | c.2451G>T p.Q817H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100505702; called by muse, mutect2, varscan2
- MRPL39 | c.722A>C p.E241A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV100220937; called by muse, mutect2, varscan2
- MRTFB | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100371281; called by muse, varscan2
- MS4A14 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.703); catalogued as COSV100280409; called by mutect2, varscan2
- MS4A6E | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100279231; called by muse, mutect2
- MS4A8 | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100282412, COSV100282517; called by muse, mutect2, varscan2
- MSANTD3 | c.743A>T p.K248M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.926); catalogued as COSV58494106; called by muse, mutect2, varscan2
- MSGN1 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV99808752; called by muse, varscan2
- MTERF3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.174); catalogued as rs1164030688, COSV99749769; called by muse, mutect2, varscan2
- MTR | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360704340, COSV100855381; called by muse, mutect2, varscan2
- MUC16 | c.38909A>G p.N12970S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs1263262397, COSV101199920; called by muse, mutect2, varscan2
- MUC16 | c.13082C>G p.T4361S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1000906064, COSV101199922; called by muse, mutect2, varscan2
- MUC16 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV101199924; called by muse, mutect2, varscan2
- MUC17 | c.12159G>T p.R4053S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100073200; called by muse, mutect2, varscan2
- MUC5B | c.7745C>A p.T2582N | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs1235562707, COSV101500132; called by muse, varscan2
- MUSK | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV51884087, COSV51901829; called by muse, mutect2, varscan2
- MXRA5 | c.4692C>A p.D1564E | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99476940; called by muse, mutect2, varscan2
- MYBPC1 | c.150G>C p.Q50H (on ENST00000550270 / NM_206820.2; = p.Q75H on NM_002465.4) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.547); catalogued as COSV100638001; called by muse, mutect2, varscan2
- MYF6 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99952803; called by muse, mutect2, varscan2
- MYH6 | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100676580, COSV62452349; called by muse, mutect2, varscan2
- MYO16 | c.3415C>A p.Q1139K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as COSV62763798; called by muse, mutect2, varscan2
- MYO5A | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100697658; called by muse, mutect2, varscan2
- MYO9B | c.6091G>A p.A2031T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs372528782; called by mutect2, varscan2
- MYORG | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1332049718, COSV99898599; called by muse, mutect2, varscan2
- MZT1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100910070; called by muse, mutect2
- NAA16 | c.1962A>T p.L654F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101049923; called by muse, mutect2, varscan2
- NALCN | c.3662T>A p.L1221Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99215147; called by muse, mutect2, varscan2
- NAV3 | c.2249G>T p.R750L | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57066953, COSV99890864; called by muse, mutect2, varscan2
- NBEA | c.5925G>T p.K1975N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100080187; called by muse, mutect2
- NCAPD3 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599365; called by muse, mutect2, varscan2
- NCL | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV100502349; called by muse, mutect2, varscan2
- NCOA1 | c.3727G>C p.A1243P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99946009; called by muse, varscan2
- NEBL | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV101009207, COSV101009372; called by muse, mutect2, varscan2
- NEBL | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV65800094; called by mutect2, varscan2
- NELL1 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.154); catalogued as rs1328867777, COSV100121418; called by muse, mutect2, varscan2
- NEUROD4 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV54472005; called by muse, mutect2, varscan2
- NEXMIF | c.3985G>T p.D1329Y | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99280804; called by muse, mutect2, varscan2
- NID1 | c.1390A>G p.M464V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs1239733994, COSV99937489; called by muse, mutect2, varscan2
- NLRC4 | c.102T>A p.N34K | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100707371; called by muse, mutect2, varscan2
- NLRP10 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs200235468, COSV100149673, COSV60779661; called by muse, mutect2, varscan2
- NLRP14 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as COSV55066600; called by muse, mutect2, varscan2
- NLRP14 | c.1588T>A p.C530S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100204965; called by muse, mutect2, varscan2
- NLRP14 | c.2334A>G p.I778M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1355587442, COSV100204967; called by muse, mutect2, varscan2
- NLRP14 | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV55072551; called by muse, mutect2, varscan2
- NLRP3 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.07); catalogued as COSV100276029, COSV60219489; called by muse, mutect2, varscan2
- NLRP3 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as COSV60233280; called by muse, varscan2
- NLRP3 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100276030; called by muse, mutect2, varscan2
- NLRP5 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV101173677; called by mutect2, varscan2
- NLRP6 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100381015, COSV56461255; called by muse, mutect2, varscan2
- NOL12 | c.479+1G>T p.X160_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100767145; called by muse, mutect2
- NOTCH4 | c.4190C>A p.P1397Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.313); catalogued as rs753178549, COSV100900675, COSV66681461; called by muse, mutect2, varscan2
- NPAP1 | c.958G>C p.A320P | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.961); catalogued as COSV100275375; called by muse, mutect2, varscan2
- NPAP1 | c.2411C>A p.S804Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1467395962, COSV100275376, COSV61507080; called by muse, mutect2, varscan2
- NPC1 | c.1672G>C p.A558P | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as CM125243, CM1312906, COSV99341327; called by muse, mutect2, varscan2
- NPHP3 | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100446916; called by muse, mutect2, varscan2
- NPR1 | c.2417+1G>T p.X806_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100902022; called by muse, varscan2
- NR1I3 | c.1006C>G p.H336D (on ENST00000367982 / NM_001077480.3; = p.H332D on NM_005122.5) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV100915667; called by muse, mutect2, varscan2
- NRG2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.537); catalogued as rs754882622, COSV99180245; called by muse, mutect2, varscan2
- NRG3 | c.1934T>A p.I645K (on ENST00000404547 / NM_001370084.1; = p.I621K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV100931398, COSV100932684; called by mutect2, varscan2
- NRXN1 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs1452706977, COSV101277583; called by muse, varscan2
- NSF | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1242871424, COSV99833826; called by muse, mutect2, varscan2
- NTRK2 | c.2153G>T p.R718L (on ENST00000323115 / NM_001369534.1; = p.R734L on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99455274; called by muse, mutect2, varscan2
- NUP153 | c.692T>A p.F231Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020283; called by muse, mutect2, varscan2
- NUP210 | c.116_117insT p.A40Gfs*5 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as COSV99596197; called by mutect2, pindel, varscan2
- NUP88 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.457); catalogued as COSV99851629; called by muse, mutect2, varscan2
- NUP98 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1293088149, COSV100262375; called by muse, mutect2, varscan2
- NUTM1 | c.3314G>A p.G1105E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100149005; called by muse, mutect2, varscan2
- NUTM2F | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV53556779, COSV99480116; called by muse, mutect2, varscan2
- NYAP2 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99796618; called by muse, mutect2, varscan2
- OBSCN | c.10285del p.E3429Sfs*17 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as COSV99484478; called by pindel, varscan2
- OCA2 | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100667861; called by muse, mutect2, varscan2
- OGFRL1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.078); catalogued as rs1174728040, COSV100965761, COSV64971795; called by muse, mutect2, varscan2
- OLFM4 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.326); catalogued as COSV99524319; called by muse, mutect2, varscan2
- OPLAH | c.2831A>G p.Y944C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101470769; called by muse, mutect2, varscan2
- OPLAH | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs782637342, COSV101470727; called by muse, mutect2
- OR10A6 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100564285; called by mutect2, varscan2
- OR10J1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.027); catalogued as COSV101419881; called by muse, mutect2, varscan2
- OR13C5 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101053104; called by muse, mutect2, varscan2
- OR1Q1 | c.795_796insA p.Y266Ifs*49 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | catalogued as COSV99939234; called by mutect2, pindel, varscan2
- OR2AK2 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823658; called by muse, mutect2, varscan2
- OR2AK2 | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs1242271288, COSV100823659; called by muse, mutect2, varscan2
- OR2G2 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100189754; called by muse, mutect2, varscan2
- OR2G6 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100598054, COSV58574350, COSV58574803; called by muse, mutect2, varscan2
- OR2T33 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100531905; called by muse, mutect2, varscan2
- OR4A15 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100124078; called by muse, mutect2, varscan2
- OR4F6 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100186908; called by muse, mutect2, varscan2
- OR4K14 | c.236C>A p.T79N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100520419; called by muse, mutect2, varscan2
- OR51F1 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58578735; called by muse, mutect2, varscan2
- OR51Q1 | c.591C>A p.N197K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100332926; called by muse, mutect2, varscan2
- OR56A1 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs756588417, COSV100360468; called by muse, mutect2, varscan2
- OR56A4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100417619, COSV58109278; called by muse, mutect2
- OR5J2 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV56621932; called by muse, mutect2, varscan2
- OR6F1 | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100129158; called by muse, mutect2, varscan2
- OR6K2 | c.310C>G p.H104D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100656781, COSV100656915; called by muse, mutect2, varscan2
- OR6Y1 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100225373; called by muse, mutect2, varscan2
- OR7A10 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.532); catalogued as COSV99932447; called by muse, mutect2, varscan2
- OR7G1 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53317224, COSV99528589; called by muse, mutect2, varscan2
- OR8H3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100538970; called by muse, mutect2
- OR8H3 | c.178A>C p.M60L | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57912101; called by muse, mutect2
- OSBPL5 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99720381; called by muse, mutect2
- OVGP1 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV63857925, COSV63859877; called by muse, mutect2, varscan2
- P2RY10 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV50680406; called by muse, mutect2, varscan2
- PAXIP1 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101249680; called by muse, mutect2, varscan2
- PCCA | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387778734, CM141964, COSV100886837; called by muse, mutect2, varscan2
- PCDH10 | c.2077G>T p.G693C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs771377776, COSV99993551; called by muse, mutect2, varscan2
- PCDH11X | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53491271; called by muse, mutect2, varscan2
- PCDH15 | c.4816del p.E1606Nfs*214 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as COSV100904366, COSV64727525; called by mutect2, pindel, varscan2
- PCDH15 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100220854; called by muse, mutect2, varscan2
- PCDH18 | c.3142G>T p.G1048C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV100787306; called by muse, mutect2, varscan2
- PCDHA13 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99166342; called by muse, mutect2, varscan2
- PCDHA2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.309); catalogued as COSV100973770; called by muse, mutect2, varscan2
- PCDHA8 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100970728; called by muse, mutect2, varscan2
- PCDHA8 | c.1613G>C p.R538P | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100969510, COSV65324504, COSV65330213; called by muse, varscan2
- PCDHB11 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as COSV99504285; called by muse, mutect2, varscan2
- PCDHB16 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99502025; called by muse, mutect2, varscan2
- PCDHB16 | c.1853G>T p.W618L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99502026; called by muse, mutect2, varscan2
- PCDHB3 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV99165162; called by muse, mutect2
- PCDHB7 | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV50805732; called by muse, mutect2, varscan2
- PCDHGA3 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV99538193; called by muse, mutect2, varscan2
- PCDHGA9 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99538210; called by muse, varscan2
- PCDHGB4 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1420676769, COSV99538208; called by muse, mutect2, varscan2
- PDE3A | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.818); catalogued as rs1202519660, COSV100762101; called by muse, mutect2, varscan2
- PDE6C | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1342170877, COSV101008748; called by mutect2, varscan2
- PDHA2 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54782320, COSV99756887; called by muse, mutect2, varscan2
- PDIA4 | c.1784G>C p.R595P (on ENST00000286091 / NM_001371244.1; = p.R594P on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs779405344, COSV99618313, COSV99618521; called by mutect2, varscan2
- PEG3 | c.3583G>T p.G1195W | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV99688920; called by muse, mutect2, varscan2
- PELP1 | c.3038G>C p.G1013A | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1383583926, COSV99342867; called by muse, mutect2, varscan2
- PGAP4 | c.393A>T p.Q131H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.263); catalogued as COSV100877836; called by muse, mutect2, varscan2
- PGBD4 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1480322005, COSV56626874; called by muse, mutect2, varscan2
- PGK1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100540665; called by muse, mutect2, varscan2
- PGM2 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV101126585; called by muse, mutect2, varscan2
- PHF8 | c.1351G>T p.D451Y (on ENST00000357988 / NM_001184896.1; = p.D415Y on NM_015107.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100154186; called by muse, mutect2, varscan2
- PHKB | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100067076; called by muse, mutect2, varscan2
- PIGO | c.1611G>T p.R537S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53054375, COSV99956588; called by muse, mutect2, varscan2
- PIM2 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV50234341, COSV99331956; called by muse, mutect2, varscan2
- PIP5K1B | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as rs754458316, COSV99598763; called by muse, mutect2, varscan2
- PKHD1L1 | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs1360331833, COSV101006134; called by muse, mutect2, varscan2
- PKHD1L1 | c.4100G>T p.G1367V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101006137; called by muse, mutect2
- PKP4 | c.2105C>A p.S702Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100733843; called by muse, mutect2, varscan2
- PLA2G4E | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs757508072, COSV101268570; called by muse, mutect2, varscan2
- PLBD2 | c.1719G>T p.M573I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99785324; called by muse, mutect2, varscan2
- PLCH1 | c.4381C>T p.Q1461* (on ENST00000340059 / NM_001130960.2; = p.Q1453* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100396845; called by muse, mutect2, varscan2
- PLEC | c.9643G>T p.V3215L (on ENST00000322810 / NM_201380.4; = p.V3105L on NM_000445.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs781825474, COSV100514047; called by muse, mutect2, varscan2
- PLEKHM3 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101216574; called by muse, mutect2, varscan2
- PLG | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99804650; called by muse, mutect2, varscan2
- PLVAP | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99391647; called by muse, varscan2
- PLXNA3 | c.1409C>A p.P470Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs782501504, COSV100859981; called by muse, mutect2
- PMPCB | c.423C>G p.Y141* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs1366756089, COSV99971264; called by muse, mutect2, varscan2
- PNLIP | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981804; called by muse, mutect2, varscan2
- PNPLA6 | c.742-1G>T p.X248_splice (on ENST00000414982 / NM_001166111.2; = p.X200_splice on NM_006702.5) | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99653701; called by muse, mutect2, varscan2
- POLRMT | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs370579134, COSV73933167; called by muse, mutect2, varscan2
- POP1 | c.2757G>T p.K919N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV100855831; called by muse, mutect2, varscan2
- PPARG | c.1071G>A p.M357I (on ENST00000287820 / NM_015869.5; = p.M327I on NM_005037.7) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1325132092, COSV99826504; called by mutect2, varscan2
- PPP1R26 | c.1837G>T p.V613L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs756198560, COSV100778066; called by muse, mutect2, varscan2
- PPP1R3A | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | catalogued as COSV99492915, COSV99492960; called by muse, mutect2, varscan2
- PPP4R3B | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99702006; called by muse, mutect2
- PQBP1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as COSV99504120, COSV99504281; called by muse, mutect2, varscan2
- PRDM11 | c.1186G>T p.E396* (on ENST00000530656 / NM_001359633.1; = p.E362* on NM_001256695.1) | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as COSV55442811, COSV99770711; called by muse, mutect2, varscan2
- PREPL | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV99576178; called by muse, mutect2
- PREX1 | c.3443G>T p.C1148F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906294, COSV64248678; called by muse, mutect2, varscan2
- PROX1 | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54783666; called by muse, mutect2, varscan2
- PRPF3 | c.360A>T p.E120D | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.899); catalogued as COSV100254789; called by muse, mutect2, varscan2
- PRR19 | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs199870306, COSV100003849; called by muse, mutect2, varscan2
- PRSS38 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816483; called by muse, mutect2, varscan2
- PRSS55 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100153777; called by muse, mutect2, varscan2
- PSD3 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs573668110, COSV100496176, COSV58967240; called by muse, mutect2, varscan2
- PSG7 | c.607T>G p.Y203D | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV101343241; called by muse, mutect2, varscan2
- PSMD3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767947232, COSV52857123, COSV99227575; called by muse, mutect2, varscan2
- PTCH1 | c.3985G>T p.G1329W | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100108570; called by muse, mutect2, varscan2
- PTPN5 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs1167145441, COSV100659903; called by muse, mutect2, varscan2
- PTPRC | c.1924T>A p.Y642N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722646; called by muse, varscan2
- PTPRG | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99874888; called by muse, mutect2, varscan2
- PUM2 | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278467675, COSV100163438, COSV100163644; called by muse, mutect2, varscan2
- PURB | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs1398721629, COSV101194940; called by muse, mutect2, varscan2
- PZP | c.1787T>A p.V596E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99737794; called by muse, mutect2
- QARS1 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100070039; called by muse, mutect2, varscan2
- RABEP2 | c.1485G>C p.Q495H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs755960017, COSV100707039; called by muse, mutect2, varscan2
- RAPGEF6 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1330214077, COSV99726461; called by muse, mutect2, varscan2
- RASGRF2 | c.647T>A p.M216K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV99429227; called by muse, mutect2, varscan2
- RASSF2 | c.540A>T p.T180= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as COSV101040757; called by muse, mutect2, varscan2
- RB1 | c.2114T>A p.M705K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99924746; called by muse, mutect2, varscan2
- RBBP9 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422951016, COSV100464047; called by muse, mutect2, varscan2
- RBM17 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101159102; called by muse, mutect2, varscan2
- REL | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99692076; called by muse, mutect2, varscan2
- REV3L | c.5491G>T p.D1831Y | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100725179; called by muse, mutect2, varscan2
- RGS5 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV100009057; called by muse, mutect2, varscan2
- RIMBP2 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV55486637; called by muse, mutect2, varscan2
- RIMKLB | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100223888; called by muse, mutect2, varscan2
- RIOX1 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100408026; called by muse, mutect2
- RIPOR2 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52417064; called by muse, mutect2, varscan2
- RNF148 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411388; called by muse, mutect2, varscan2
- RNF150 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153437; called by muse, mutect2, varscan2
- RNF220 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100698573; called by muse, mutect2, varscan2
- ROBO2 | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as COSV100166736, COSV59937523; called by muse, mutect2, varscan2
- ROS1 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.816); catalogued as COSV100877065, COSV63853406; called by mutect2, varscan2
- RP1 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as CD004583, COSV55111983, COSV99607470; called by muse, mutect2, varscan2
- RP1L1 | c.2101G>T p.V701L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV101223246; called by muse, mutect2, varscan2
- RPA4 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100232776; called by muse, varscan2
- RPAP3 | c.240C>G p.N80K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV99139377; called by muse, mutect2, varscan2
- RPL8 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV99369868; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.195A>T p.R65S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100402488; called by muse, mutect2, varscan2
- RPS6KA2 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99690836; called by muse, mutect2, varscan2
- RRM2 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV100459667; called by muse, mutect2, varscan2
- RSBN1L | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100616045; called by muse, mutect2
- RTL9 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101511686; called by muse, mutect2, varscan2
- RTTN | c.3219G>C p.Q1073H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99732365; called by muse, mutect2, varscan2
- RUVBL1 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494162; called by muse, mutect2, varscan2
- RYR2 | c.4762G>T p.V1588L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV100768849; called by muse, mutect2, varscan2
- RYR2 | c.6082C>A p.R2028S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100770120, COSV63695525; called by muse, mutect2, varscan2
- RYR2 | c.9255C>A p.N3085K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV100770121, COSV63688243; called by muse, mutect2
- RYR2 | c.9256C>A p.Q3086K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as rs1439674246, COSV100770123; called by muse, mutect2
- RYR2 | c.10745C>A p.S3582Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100770124; called by muse, mutect2, varscan2
- RYR3 | c.8929C>A p.H2977N (on ENST00000389232; = p.H2978N on NM_001036.6) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV101212569; called by muse, mutect2
- SAGE1 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100187225; called by muse, mutect2, varscan2
- SALL1 | c.3707A>G p.Q1236R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV99173848; called by muse, mutect2, varscan2
- SCAND1 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV100018907; called by muse, mutect2, varscan2
- SCN10A | c.3194G>A p.W1065* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1347009711, COSV101479388; called by muse, mutect2, varscan2
- SCN11A | c.5261G>T p.G1754V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100181549, COSV56568086; called by muse, mutect2, varscan2
- SCN3A | c.2878T>A p.C960S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99326987; called by muse, mutect2, varscan2
- SCN5A | c.5737C>G p.R1913G (on ENST00000333535 / NM_198056.3; = p.R1912G on NM_000335.5) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61120831; called by muse, mutect2
- SCNN1G | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100264186; called by muse, mutect2, varscan2
- SEC23IP | c.2908C>G p.H970D | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100956871; called by mutect2, varscan2
- SECISBP2L | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99960347; called by muse, mutect2, varscan2
- SELP | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs35392020, COSV99739931; called by muse, mutect2, varscan2
- SERPINA9 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs779518053, COSV100098358; called by muse, mutect2, varscan2
- SETBP1 | c.1107G>T p.R369S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as COSV99953291; called by muse, mutect2, varscan2
- SETD2 | c.3997G>T p.D1333Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100338983; called by mutect2, varscan2
- SH3KBP1 | c.1040T>A p.V347D | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV101114755; called by muse, varscan2
- SHROOM4 | c.3901C>A p.L1301I | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs1557247863, COSV99173528; called by muse, mutect2, varscan2
- SI | c.2301T>A p.S767= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100015518; called by muse, mutect2, varscan2
- SI | c.359C>G p.T120R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100015519; called by muse, mutect2, varscan2
- SIGLEC1 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753674149, COSV99165191; called by muse, mutect2, varscan2
- SIX3 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV99578352; called by muse, mutect2
- SIX6 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100576493; called by muse, mutect2, varscan2
- SKIV2L | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs143205619; called by muse, mutect2, varscan2
- SLC12A3 | c.1816A>T p.K606* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99344232; called by muse, mutect2, varscan2
- SLC12A5 | c.1118C>A p.A373D (on ENST00000454036 / NM_001134771.2; = p.A350D on NM_020708.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV99716033; called by muse, mutect2, varscan2
- SLC12A9 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99307819; called by muse, mutect2, varscan2
- SLC16A10 | c.580T>G p.Y194D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100920877; called by muse, mutect2, varscan2
- SLC16A9 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101264385; called by muse, mutect2, varscan2
579 further variants in this file (266 protein-altering or splice-affecting, 287 silent, 26 other) are not listed here.
